Somatic mutation profile of tumor specimen TCGA-CV-6945-01A (aliquot TCGA-CV-6945-01A-11D-1912-08) from TCGA case TCGA-CV-6945, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 41.5 years (15,158 days).
Specimen TCGA-CV-6945-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2af2afc0-f8c7-471e-b554-882e0c988c6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6945-10A (Blood Derived Normal), aliquot TCGA-CV-6945-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bf72b9e-dd70-4377-a946-f055ee38d252

The open-access MAF lists 135 somatic variants for this specimen: 94 protein-altering or splice-affecting, 38 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 38, Splice Site 5, Frame Shift Del 5, Nonsense Mutation 4, Intron 2, Frame Shift Ins 2, Splice Region 1, Translation Start Site 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 36/100 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.51); PolyPhen benign (0.366); catalogued as COSV55875690, COSV55899999; called by muse, mutect2, varscan2
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 30/50 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.4638G>T p.M1546I | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV53968903, COSV53988054, COSV99687607; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); catalogued as COSV99865626; called by mutect2, varscan2
- ADAM22 | c.1888G>T p.G630* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as COSV99718639; called by muse, mutect2, varscan2
- AKAP5 | c.1283G>C p.*428Sext*? (on ENST00000320636; = p.*428Sext*27 on NM_004857.3) | Nonstop Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as COSV100278110; called by muse, mutect2, varscan2
- AMER2 | c.1786C>A p.L596M | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.832); catalogued as COSV100766415; called by muse, mutect2, varscan2
- AMY2B | c.461G>C p.G154A | Missense Mutation (SNP) | VAF 69/662 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100796549; called by muse, mutect2, varscan2
- APPL2 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99315200; called by muse, mutect2, varscan2
- ARGFX | c.384C>A p.N128K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100544238; called by muse, mutect2, varscan2
- ARHGAP35 | c.4202G>A p.W1401* | Nonsense Mutation (SNP) | VAF 40/309 reads (13%) | catalogued as COSV101351190; called by muse, mutect2, varscan2
- ARPP21 | c.682A>T p.R228* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV99493681; called by muse, mutect2, varscan2
- ASAP1 | c.2122A>G p.N708D | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as rs191199415, COSV100728026; called by muse, mutect2, varscan2
- ASNS | c.1457A>T p.Q486L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV99446899; called by muse, mutect2, varscan2
- ASNSD1 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99641438; called by muse, mutect2, varscan2
- ATP4A | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); catalogued as rs904563816, COSV52871892; called by muse, mutect2, varscan2
- BEX5 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV100375099; called by muse, mutect2, varscan2
- BOD1L1 | c.6487A>C p.K2163Q | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99240578; called by muse, mutect2, varscan2
- BRCA2 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs80358469, COSV66454252; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CBWD2 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99380894; called by muse, mutect2, varscan2
- CELSR1 | c.3676C>T p.L1226F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.707); catalogued as COSV99420443; called by muse, mutect2, varscan2
- CMTR2 | c.616A>T p.N206Y | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100579389; called by muse, mutect2, varscan2
- CREBRF | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as COSV99756515; called by muse, mutect2, varscan2
- CSMD3 | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.197); catalogued as COSV99850760; called by muse, mutect2
- CTNNA2 | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100562303; called by muse, mutect2, varscan2
- CUBN | c.9106+2T>A p.X3036_splice | Splice Site (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100913702; called by muse, mutect2, varscan2
- CYP1A2 | c.1508G>T p.R503L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV100673949; called by muse, mutect2, varscan2
- DCAF4L2 | c.148C>A p.R50S | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV60479615, COSV60480142; called by muse, mutect2, varscan2
- DNAH5 | c.13126-1G>A p.X4376_splice | Splice Site (SNP) | VAF 33/97 reads (34%) | catalogued as COSV99455278; called by muse, mutect2, varscan2
- DNAH8 | c.4880G>A p.R1627H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV59427646; called by muse, mutect2
- EIF4G1 | c.1690C>T p.P564S (on ENST00000346169 / NM_198241.3; = p.P368S on NM_004953.5) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs762917023, COSV100072388; called by mutect2, varscan2
- FAM135B | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV52708540; called by muse, mutect2, varscan2
- FBH1 | c.442C>T p.P148S (on ENST00000362091 / NM_178150.3; = p.P199S on NM_032807.4) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100758980; called by muse, mutect2, varscan2
- FRAS1 | c.2471G>T p.G824V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99356428; called by muse, mutect2, varscan2
- GLRX3 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755871807, COSV58692613; called by muse, mutect2, varscan2
- HERC2 | c.3355G>A p.A1119T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs754085213, COSV99877444; called by muse, mutect2, varscan2
- HTT | c.2394A>T p.T798= | Splice Region (SNP) | VAF 47/161 reads (29%) | catalogued as COSV100751365; called by muse, mutect2, varscan2
- IQCE | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100383823, COSV58076567; called by muse, mutect2, varscan2
- IQGAP3 | c.1895T>A p.L632* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100752449; called by muse, mutect2, varscan2
- ITGA8 | c.329C>A p.P110Q | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.44); PolyPhen probably damaging (1); catalogued as COSV100959875; called by muse, mutect2, varscan2
- KRT13 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs771074447, COSV99877542; called by muse, mutect2, varscan2
- KRT83 | c.1192A>T p.M398L | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV99531986; called by muse, mutect2, varscan2
- KRTAP13-2 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV101299671; called by muse, mutect2, varscan2
- LILRB1 | c.477C>G p.I159M (on ENST00000427581; = p.I123M on NM_006669.6) | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100208013, COSV61118723; called by muse, mutect2, varscan2
- LMO7 | c.2294C>T p.T765M (on ENST00000357063; = p.T446M on NM_005358.5) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763725582, COSV100413970; called by muse, mutect2, varscan2
- LRP1 | c.94T>C p.F32L | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99677667; called by muse, mutect2, varscan2
- MMP24 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs1472659857, COSV55774359; called by muse, mutect2
- MPRIP | c.2645G>A p.G882E | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1237845761, COSV100506189; called by muse, mutect2, varscan2
- NLRP2 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs527958520, COSV54753596, COSV99672595; called by muse, mutect2, varscan2
- NLRP4 | c.1581A>G p.I527M | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV100017359; called by muse, mutect2, varscan2
- OR2M3 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 90/335 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as COSV101513540, COSV71758998; called by muse, mutect2, varscan2
- OR5A1 | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs769455556, COSV57376134; called by muse, mutect2, varscan2
- OR5H2 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100788878, COSV62351407; called by muse, mutect2, varscan2
- OSR1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55345784; called by muse, mutect2, varscan2
- PCDHA1 | c.233A>T p.N78I | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV100974566; called by muse, mutect2, varscan2
- PCDHB2 | c.1333G>C p.D445H | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99166474, COSV99166978; called by muse, mutect2, varscan2
- PCLO | c.5468C>T p.P1823L | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs758637592, COSV100439060; called by muse, mutect2, varscan2
- PHOX2B | c.906C>G p.N302K | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV56929657, COSV99891770; called by muse, mutect2, varscan2
- PKP4 | c.3009+2T>G p.X1003_splice | Splice Site (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100734021; called by muse, mutect2, varscan2
- PTPN13 | c.6069A>T p.K2023N (on ENST00000411767 / NM_080683.3; = p.K2004N on NM_006264.3) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100365561; called by muse, mutect2
- RABIF | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV100936384; called by muse, mutect2, varscan2
- RAP1GAP | c.473A>T p.K158M | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV99266101; called by muse, mutect2, varscan2
- RBM11 | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT tolerated, low confidence (0.59); PolyPhen probably damaging (0.923); catalogued as COSV101271251, COSV68748064; called by muse, varscan2
- RBM11 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV101271252; called by muse, varscan2
- RPGRIP1L | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100047016; called by muse, mutect2, varscan2
- SCEL | c.1277G>T p.G426V (on ENST00000349847 / NM_144777.3; = p.G406V on NM_003843.4) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100582613, COSV62992984; called by muse, mutect2, varscan2
- SLC15A2 | c.1036-1G>T p.X346_splice | Splice Site (SNP) | VAF 31/215 reads (14%) | catalogued as COSV55200026; called by muse, mutect2, varscan2
- SLC2A14 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.019); catalogued as rs771821320, COSV61585468; called by muse, mutect2, varscan2
- SLC38A9 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); catalogued as COSV100591622; called by muse, mutect2, varscan2
- SLC7A14 | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99201134; called by muse, mutect2, varscan2
- SLCO1B3 | c.2059G>C p.D687H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV53932974, COSV99682392; called by muse, mutect2, varscan2
- SLCO5A1 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.018); catalogued as COSV99481268; called by muse, mutect2, varscan2
- SMG8 | c.1048A>T p.M350L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99959151; called by muse, mutect2, varscan2
- TANK | c.955A>G p.I319V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99376625; called by muse, mutect2, varscan2
- TAS2R38 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/72 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.979); catalogued as COSV101516575; called by muse, mutect2, varscan2
- TMEM106B | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101188891, COSV67544466; called by muse, mutect2, varscan2
- UBAP1 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as COSV99903660; called by muse, mutect2, varscan2
- USP5 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs781905870, COSV99979133; called by muse, mutect2, varscan2
- VPS39 | c.774T>G p.I258M (on ENST00000348544 / NM_001301138.2; = p.I247M on NM_015289.5) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV100529683; called by muse, mutect2, varscan2
- YLPM1 | c.2441G>A p.R814Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99459136, COSV99461629; called by muse, mutect2, varscan2
- ZNF141 | c.982A>G p.K328E | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV99550074; called by muse, mutect2, varscan2
- ZNF644 | c.2878C>T p.L960F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100494786; called by muse, mutect2, varscan2
- ZSCAN18 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0.027); catalogued as COSV99559803; called by muse, mutect2, varscan2
- ZXDA | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100699492; called by muse, mutect2, varscan2
- DAPK3 | c.162del p.V56* | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | called by mutect2, pindel, varscan2
- HEATR9 | c.139-1G>T p.X47_splice | Splice Site (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- HROB | c.1444_1449+1del | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | called by mutect2, pindel, varscan2
- IGKV6D-41 | c.310G>C p.A104P | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IRF9 | c.77_98del p.P26Qfs*240 | Frame Shift Del (DEL) | VAF 33/159 reads (21%) | called by mutect2, pindel, varscan2
- NSUN7 | c.146dup p.M49Ifs*25 | Frame Shift Ins (INS) | VAF 25/144 reads (17%) | called by mutect2, pindel, varscan2
- NYX | c.1209dup p.E404Rfs*89 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- PSIP1 | c.619_628del p.E207Sfs*55 | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | called by mutect2, pindel, varscan2
- THBS2 | c.138_139del p.G47Afs*14 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by pindel, varscan2
- WASHC2A | c.3400G>A p.D1134N | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADRA2C | c.634C>T p.L212= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1279787732, COSV57467452; called by muse, mutect2, varscan2
- ANXA8L1 | c.333C>G p.T111= | Silent (SNP) | VAF 3/12 reads (25%) | called by mutect2, varscan2
- ATN1 | c.1935C>G p.S645= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV63113294; called by muse, mutect2
- B3GAT1 | c.324G>A p.T108= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs759514133, COSV100438252; called by muse, varscan2
- BRINP1 | c.270G>A p.L90= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1473261931, COSV99777018, COSV99777162; called by muse, mutect2, varscan2
- C19orf12 | c.378G>A p.E126= (on ENST00000392278 / NM_001031726.3; = p.E115= on NM_031448.6) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs768396080, COSV100080663; called by muse, varscan2
- CATSPERG | c.3198C>A p.A1066= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99287014; called by muse, mutect2, varscan2
- CFAP45 | c.1392G>A p.E464= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100928685; called by muse, mutect2, varscan2
- CHRAC1 | c.33C>A p.G11= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99636307; called by muse, varscan2
- CX3CR1 | c.1038G>C p.T346= | Silent (SNP) | VAF 50/142 reads (35%) | catalogued as COSV64193915, COSV64194263; called by muse, mutect2, varscan2
- DPYSL4 | c.1002C>T p.C334= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1010205493, COSV100634076; called by muse, mutect2, varscan2
- DUSP21 | c.513G>C p.S171= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100173690; called by muse, mutect2, varscan2
- FAM47C | c.711G>A p.E237= | Silent (SNP) | VAF 39/55 reads (71%) | catalogued as COSV100793000; called by muse, mutect2, varscan2
- FGF14 | c.654C>G p.V218= | Silent (SNP) | VAF 49/92 reads (53%) | catalogued as COSV101087989; called by muse, mutect2, varscan2
- FLII | c.1209G>T p.A403= | Silent (SNP) | VAF 51/154 reads (33%) | catalogued as COSV100493480, COSV58948512; called by muse, mutect2, varscan2
- ICE1 | c.6558A>T p.P2186= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99665962; called by muse, mutect2
- KCTD8 | c.1188A>T p.A396= | Silent (SNP) | VAF 42/262 reads (16%) | catalogued as COSV100760220; called by muse, mutect2, varscan2
- MYH15 | c.822G>T p.V274= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99844522; called by muse, mutect2, varscan2
- MYO1H | c.1458G>C p.L486= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100184097, COSV60447376; called by muse, mutect2, varscan2
- MZF1 | c.1881C>T p.C627= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs944207806, COSV99285501; called by muse, mutect2, varscan2
- NCKAP5 | c.1374G>T p.G458= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100492048, COSV100494722; called by muse, mutect2, varscan2
- NEXMIF | c.1596C>G p.T532= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV99280581; called by muse, mutect2, varscan2
- NPAS4 | c.2325G>A p.G775= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs780780487, COSV100215328; called by muse, mutect2, varscan2
- NRDC | c.543A>G p.E181= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100703799; called by muse, mutect2, varscan2
- OR5A2 | c.186C>T p.F62= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV100119867; called by muse, mutect2, varscan2
- OTOF | c.5908T>C p.L1970= (on ENST00000272371 / NM_194248.3; = p.L1203= on NM_004802.4) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99719273; called by muse, mutect2
- PCDHA8 | c.1857C>A p.R619= | Silent (SNP) | VAF 49/164 reads (30%) | catalogued as rs1188166294, COSV100970194; called by muse, mutect2, varscan2
- PITPNM2 | c.1320G>A p.G440= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as COSV99759848; called by muse, mutect2, varscan2
- PLK1 | c.1446C>T p.F482= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as rs1406259456, COSV55623129; called by muse, mutect2, varscan2
- PXMP2 | c.138A>T p.A46= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV100268623; called by muse, mutect2, varscan2
- RGS14 | c.681G>T p.G227= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV101281764; called by muse, mutect2, varscan2
- SDSL | c.435C>A p.P145= | Silent (SNP) | VAF 28/149 reads (19%) | catalogued as COSV100615318; called by muse, mutect2, varscan2
- SHANK3 | c.1497C>T p.G499= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs778220079, COSV53187342, COSV99436306; called by muse, mutect2, varscan2
- SLC4A8 | c.963G>T p.L321= | Silent (SNP) | VAF 40/240 reads (17%) | catalogued as COSV100177687; called by muse, mutect2, varscan2
- TOX4 | c.669T>C p.P223= | Silent (SNP) | VAF 61/133 reads (46%) | catalogued as COSV99398698; called by muse, mutect2, varscan2
- TTN | c.77602C>A p.R25868= (on ENST00000591111; = p.R18444= on NM_003319.4) | Silent (SNP) | VAF 44/180 reads (24%) | catalogued as COSV100634282, COSV59910624; called by muse, mutect2, varscan2
- ZBED4 | c.1947C>T p.Y649= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs759274549, COSV99351836; called by muse, mutect2, varscan2
- ZNF786 | c.2067G>T p.A689= | Silent (SNP) | VAF 56/203 reads (28%) | catalogued as COSV100303039, COSV60275508; called by muse, mutect2, varscan2
- FBXL13 | c.496-5507G>T | Intron (SNP) | VAF 22/95 reads (23%) | catalogued as COSV100502250; called by muse, mutect2, varscan2
- MIR520A | n.17C>A | RNA (SNP) | VAF 36/202 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.10360+4874C>T | Intron (SNP) | VAF 12/66 reads (18%) | catalogued as rs773516244, COSV100634286; called by muse, mutect2, varscan2
